Somatic mutation profile of tumor specimen 0DGMHK from CCDI case PBBTEM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.2 years (2,991 days).
Specimen 0DGMHK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9209255f-975c-4066-b583-ddf3a5268812.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGMHY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa388d27-1819-4e4d-b2dc-94f94ffd7a98

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 418/941 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 384/844 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PARP3 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 162/608 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs377163298; called by muse, mutect2, varscan2
- SLC39A12 | c.260T>A p.L87Q | Missense Mutation (SNP) | VAF 352/749 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as COSV66201077; called by muse, mutect2, varscan2
- ARID1A | c.6109dup p.Q2037Pfs*62 | Frame Shift Ins (INS) | VAF 212/750 reads (28%) | called by mutect2, varscan2
- DSTYK | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 483/1059 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRICKLE3 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 265/636 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE2 | c.18111G>A p.W6037* | Nonsense Mutation (SNP) | VAF 425/1451 reads (29%) | called by muse, mutect2, varscan2
- HBS1L | c.1833C>T p.A611= | Silent (SNP) | VAF 56/889 reads (6%) | catalogued as rs558751030; called by muse, mutect2
- OR10Q1 | c.426C>T p.R142= | Silent (SNP) | VAF 492/1075 reads (46%) | catalogued as COSV57469838; called by muse, mutect2, varscan2
- RPL10L | c.432C>T p.N144= | Silent (SNP) | VAF 242/554 reads (44%) | catalogued as rs1464110614, COSV53559837; called by muse, mutect2, varscan2
- TULP1 | c.912G>A p.T304= | Silent (SNP) | VAF 413/420 reads (98%) | catalogued as rs765820404, COSV57692047; called by muse, varscan2
- ACSM2A | c.974+75C>T | Intron (SNP) | VAF 47/169 reads (28%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/153 reads (5%) | called by muse, mutect2
